Somatic mutation profile of tumor specimen TCGA-CM-5864-01A (aliquot TCGA-CM-5864-01A-01D-1650-10) from TCGA case TCGA-CM-5864, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage I; Age at diagnosis: 60.8 years (22,219 days).
Specimen TCGA-CM-5864-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8346ca95-33ca-4234-a757-dec8bcd60176.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-5864-10A (Blood Derived Normal), aliquot TCGA-CM-5864-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/489cfc6e-f2fa-4cf3-8e2d-46f8c4c0d436

The open-access MAF lists 211 somatic variants for this specimen: 151 protein-altering or splice-affecting, 58 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 58, Nonsense Mutation 11, Frame Shift Del 3, In Frame Del 1, RNA 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4189G>T p.E1397* | Nonsense Mutation (SNP) | VAF 178/207 reads (86%) | hotspot (GDC flag); catalogued as CM992136, COSV57321785, COSV57346425; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 110/240 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as CM921040, COSV52675189, COSV52691512, COSV52734317, COSV52740807; called by muse, mutect2, varscan2
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 26/50 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA1 | c.1967T>A p.I656N | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV101037020; called by muse, mutect2, varscan2
- ABCD3 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 82/425 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs769166618, COSV59865619, COSV59866153; called by muse, mutect2
- ABHD2 | c.1123G>C p.G375R | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61773322; called by muse, mutect2
- ADAM29 | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV100822027; called by muse, mutect2, varscan2
- AGAP2 | c.1957C>T p.R653C (on ENST00000547588 / NM_001122772.2; = p.R317C on NM_014770.4) | Missense Mutation (SNP) | VAF 144/250 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1173922343, COSV57727385; called by muse, mutect2
- AL592490.1 | c.1168G>T p.V390F | Missense Mutation (SNP) | VAF 167/265 reads (63%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); catalogued as COSV69425332; called by muse, mutect2, varscan2
- ALMS1 | c.10380T>G p.I3460M | Missense Mutation (SNP) | VAF 95/277 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV52506193; called by muse, mutect2, varscan2
- ANK2 | c.5633A>G p.H1878R | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); catalogued as COSV100001803; called by muse, mutect2
- ANKMY1 | c.1319G>T p.G440V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.163); catalogued as COSV56031647; called by muse, mutect2, varscan2
- ANXA4 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67848578; called by muse, mutect2, varscan2
- ATP2A2 | c.2740A>T p.S914C | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV57875182; called by muse, mutect2, varscan2
- AUTS2 | c.3586C>T p.R1196C | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1482454954, COSV100717284; called by muse, mutect2, varscan2
- BEND5 | c.1154A>C p.E385A | Missense Mutation (SNP) | VAF 164/554 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV65716750; called by muse, mutect2, varscan2
- BNC1 | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.132); catalogued as COSV61756931; called by muse, mutect2, varscan2
- BRCA1 | c.2441T>C p.L814P | Missense Mutation (SNP) | VAF 46/274 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.345); catalogued as COSV58786789; called by muse, mutect2, varscan2
- BRWD3 | c.5116G>C p.G1706R | Missense Mutation (SNP) | VAF 208/228 reads (91%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.131); catalogued as COSV64745635; called by muse, mutect2, varscan2
- BSN | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 122/248 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV56516428; called by muse, mutect2, varscan2
- C9orf135 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 132/313 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as rs372834896; called by muse, varscan2
- CALR3 | c.210G>T p.Q70H | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); catalogued as COSV54168958; called by muse, mutect2, varscan2
- CAPN12 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs373317576; called by muse, mutect2, varscan2
- CAT | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144190885, CM055114; called by muse, mutect2, varscan2
- CATSPER1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as rs754843613, COSV56409554; called by muse, mutect2, varscan2
- CATSPERD | c.1582G>C p.G528R | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58464740; called by muse, mutect2
- CC2D2A | c.4700C>T p.P1567L | Missense Mutation (SNP) | VAF 102/217 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV58010258; called by muse, mutect2, varscan2
- CCDC30 | c.878G>A p.R293Q (on ENST00000340612; = p.R250Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 222/409 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373549506, COSV59605235; called by muse, mutect2, varscan2
- CCT8L2 | c.766C>G p.P256A | Missense Mutation (SNP) | VAF 71/218 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV63461956; called by muse, mutect2, varscan2
- CDH9 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 73/469 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99145144; called by muse, varscan2
- CENPV | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV55332992; called by muse, mutect2, varscan2
- CEP170B | c.2386G>A p.A796T (on ENST00000453495; = p.A725T on NM_015005.3) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773284189, COSV101371521, COSV69024901; called by mutect2, varscan2
- CFHR2 | c.659A>T p.K220I | Missense Mutation (SNP) | VAF 93/547 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV66380794; called by muse, mutect2, varscan2
- CHRNA2 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs376970816; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- CNTN1 | c.1711C>T p.R571* | Nonsense Mutation (SNP) | VAF 18/142 reads (13%) | catalogued as rs1174434961, COSV61637642; called by muse, varscan2
- CNTN1 | c.2534G>T p.W845L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61637647; called by muse, mutect2, varscan2
- CNTNAP4 | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 81/163 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.453); catalogued as rs761022747, COSV56671672, COSV56676533; called by muse, mutect2, varscan2
- COG8 | c.1390G>C p.A464P | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as COSV54742041; called by muse, mutect2, varscan2
- COL4A1 | c.1984C>A p.P662T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.996); catalogued as rs544300625, COSV101011198; called by muse, mutect2, varscan2
- COPB1 | c.2783G>C p.R928T | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51447424; called by muse, varscan2
- CR1 | c.2795G>T p.S932I | Missense Mutation (SNP) | VAF 45/308 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV100887630; called by muse, varscan2
- CSMD1 | c.1664C>A p.P555Q (on ENST00000520002; = p.P554Q on NM_033225.6) | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100146199, COSV59305236; called by muse, mutect2, varscan2
- CTCF | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 71/122 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50463912; called by muse, mutect2, varscan2
- CYP4A22 | c.1468C>G p.P490A | Missense Mutation (SNP) | VAF 30/151 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.139); catalogued as COSV53739076, COSV53741220; called by muse, mutect2
- CYP4F22 | c.1511G>T p.R504L | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV54111702, COSV99512818; called by muse, mutect2
- DAW1 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 185/416 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs975748242, COSV59364401; called by muse, mutect2, varscan2
- DDX28 | c.1401G>T p.E467D | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV60105680; called by muse, mutect2, varscan2
- DDX60L | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs748422357, COSV52710829; called by muse, mutect2, varscan2
- DEAF1 | c.802C>T p.Q268* | Nonsense Mutation (SNP) | VAF 9/59 reads (15%) | catalogued as COSV58606383; called by muse, mutect2, varscan2
- DGCR2 | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV54217522; called by muse, mutect2, varscan2
- DGKH | c.2153G>T p.R718I | Missense Mutation (SNP) | VAF 125/240 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV54929568; called by muse, mutect2, varscan2
- DMD | c.7244G>A p.R2415H | Missense Mutation (SNP) | VAF 281/301 reads (93%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs373749120, COSV58899961; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- DNASE2 | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.582); catalogued as COSV99262984; called by muse, varscan2
- E2F7 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 30/754 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV100523535; called by muse, mutect2
- EYA2 | c.1602G>C p.E534D | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.147); catalogued as COSV57940388; called by muse, mutect2, varscan2
- FAM13C | c.935A>C p.K312T | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV53245440; called by muse, mutect2, varscan2
- FAM216B | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780992016, COSV58270192; called by muse, mutect2, varscan2
- FAT3 | c.12926C>T p.A4309V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as COSV53091052; called by muse, mutect2, varscan2
- FAT4 | c.4235A>T p.D1412V | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101272362; called by muse, mutect2, varscan2
- FOXN3 | c.296C>A p.A99D | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV54306133, COSV54316878; called by muse, mutect2, varscan2
- FOXO4 | c.606C>A p.S202R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV58574953; called by muse, mutect2, varscan2
- FSHR | c.835G>C p.A279P | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.625); catalogued as COSV100437247; called by muse, mutect2
- FSTL5 | c.1431del p.K477Nfs*62 | Frame Shift Del (DEL) | VAF 66/250 reads (26%) | catalogued as COSV60186352; called by mutect2, pindel, varscan2
- FZD1 | c.1939G>T p.V647F | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV55309589; called by muse, mutect2, varscan2
- GABRQ | c.827C>G p.T276S | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.061); catalogued as COSV100941285; called by muse, mutect2
- GINS3 | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as COSV58919502; called by muse, mutect2, varscan2
- GPAA1 | c.857G>T p.G286V | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV60155474; called by muse, mutect2, varscan2
- GRIK1 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1463409726, COSV58713735; called by muse, mutect2, varscan2
- HAPLN3 | c.34C>A p.L12M | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as rs763692640, COSV100613754; called by muse, mutect2, varscan2
- HDAC9 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 481/885 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1400537160, COSV67769993; called by muse, mutect2, varscan2
- HLX | c.616G>T p.G206W | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV65044540; called by muse, mutect2, varscan2
- IQUB | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 55/172 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61238166; called by muse, mutect2, varscan2
- KCTD16 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.187); catalogued as COSV72577412; called by muse, varscan2
- KIAA1549 | c.1688G>A p.S563N | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV54309266; called by muse, mutect2, varscan2
- KLHL5 | c.1814T>C p.V605A | Missense Mutation (SNP) | VAF 95/201 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs939233611, COSV54672840; called by muse, mutect2, varscan2
- KNL1 | c.3737G>A p.G1246E (on ENST00000346991 / NM_170589.5; = p.G1220E on NM_144508.5) | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61152881; called by muse, mutect2, varscan2
- KRTCAP2 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 150/330 reads (45%) | catalogued as rs199976320; called by muse, mutect2, varscan2
- MAB21L2 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58261164; called by muse, mutect2, varscan2
- MAMLD1 | c.2152A>G p.S718G | Missense Mutation (SNP) | VAF 90/157 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV53373226; called by muse, mutect2
- MAP1A | c.3644A>T p.K1215M | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); catalogued as COSV55807343; called by muse, mutect2, varscan2
- MAP6 | c.1256C>A p.T419N | Missense Mutation (SNP) | VAF 121/629 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.188); catalogued as COSV59074870; called by muse, mutect2, varscan2
- MEIS3 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.578); catalogued as COSV58983087; called by muse, mutect2, varscan2
- MPDU1 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs777819415, COSV51467900; called by muse, mutect2, varscan2
- MUC1 | c.65C>G p.T22R | Missense Mutation (SNP) | VAF 86/158 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as COSV58112367; called by muse, mutect2, varscan2
- MUC6 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371028728; called by muse, mutect2, varscan2
- MYCBP2 | c.7768G>T p.E2590* (on ENST00000357337; = p.E2628* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 54/366 reads (15%) | catalogued as COSV62013333; called by muse, mutect2, varscan2
- MYH7B | c.2614G>A p.V872I | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs943547103, COSV53417162; called by muse, mutect2, varscan2
- NRXN3 | c.310G>A p.D104N (on ENST00000557594 / NM_001272020.2; = p.D736N on NM_004796.6) | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV55320612; called by muse, mutect2, varscan2
- OR10X1 | c.59T>C p.I20T | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV63767587; called by muse, mutect2, varscan2
- OR2A4 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 112/808 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as rs1422619501, COSV100199684; called by muse, mutect2
- OVCH1 | c.1553A>C p.K518T | Missense Mutation (SNP) | VAF 95/357 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV58961028, COSV58962932; called by muse, mutect2, varscan2
- PARVB | c.652C>A p.H218N | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.028); catalogued as COSV58685050; called by muse, mutect2, varscan2
- PCNT | c.4526C>T p.A1509V | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs777616514, COSV100855557; called by muse, mutect2, varscan2
- PDCD4 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54522221; called by muse, mutect2, varscan2
- PIK3C2G | c.3550C>G p.P1184A (on ENST00000676171; = p.P1143A on NM_004570.5) | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56825082, COSV99851782; called by muse, mutect2
- PLEKHA7 | c.1403A>C p.E468A | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.411); catalogued as COSV100850284; called by muse, mutect2, varscan2
- PLG | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 63/169 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs374903528; called by muse, mutect2, varscan2
- PPP1R16B | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55375541; called by muse, varscan2
- PRKD1 | c.760G>T p.G254* | Nonsense Mutation (SNP) | VAF 80/367 reads (22%) | catalogued as COSV59562653; called by muse, mutect2, varscan2
- PRLR | c.1009G>C p.G337R | Missense Mutation (SNP) | VAF 99/424 reads (23%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.494); catalogued as COSV51494110; called by muse, mutect2, varscan2
- PRRC2B | c.2785C>A p.H929N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV61935261; called by muse, mutect2, varscan2
- PSKH2 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 164/231 reads (71%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52609805; called by muse, mutect2, varscan2
- PTCD1 | c.1615G>C p.A539P | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777646870, COSV52862230, COSV99464629; called by muse, mutect2, varscan2
- RELN | c.3763T>C p.W1255R | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100633849; called by muse, mutect2
- RP1 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1178043951, COSV55111774; called by muse, mutect2
- SCN9A | c.3440A>T p.N1147I (on ENST00000303354; = p.N1136I on NM_002977.3) | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV57604450; called by muse, mutect2, varscan2
- SCN9A | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 87/220 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs775461240, COSV57604465; called by muse, mutect2, varscan2
- SCPEP1 | c.1273T>C p.W425R | Missense Mutation (SNP) | VAF 47/231 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51853658; called by muse, mutect2
- SH3D21 | c.1642G>A p.G548R (on ENST00000453908 / NM_001162530.2; = p.G437R on NM_024676.5) | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV54633791; called by muse, mutect2, varscan2
- SLC12A7 | c.1894A>T p.I632F | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV53755615; called by muse, mutect2, varscan2
- SLC13A3 | c.1307G>C p.G436A | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV51713394; called by muse, mutect2, varscan2
- SLC16A4 | c.1187C>A p.T396N | Missense Mutation (SNP) | VAF 126/295 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV63916151; called by muse, mutect2, varscan2
- SLC19A2 | c.1378G>A p.A460T | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV52546631; called by muse, mutect2, varscan2
- SLC23A2 | c.1625-1G>A p.X542_splice | Splice Site (SNP) | VAF 48/123 reads (39%) | catalogued as COSV57772578; called by muse, mutect2, varscan2
- SLC28A1 | c.76G>C p.A26P | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.451); catalogued as rs78600895, COSV54477584; called by muse, mutect2, varscan2
- SLC4A10 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 127/389 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV55770441, COSV55804080; called by muse, mutect2, varscan2
- SLFNL1 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs779945577, COSV57234289; called by muse, mutect2, varscan2
- SMAD1 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV100129754; called by muse, mutect2, varscan2
- SMPX | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 326/354 reads (92%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.061); catalogued as rs746359009, COSV65277225; called by muse, mutect2, varscan2
- SOBP | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57996818, COSV58000590; called by muse, mutect2, varscan2
- SPAG9 | c.2116G>A p.V706I (on ENST00000262013 / NM_001130528.3; = p.V692I on NM_003971.6) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56233279; called by muse, mutect2, varscan2
- SPOCK3 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 82/334 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62721021; called by muse, mutect2, varscan2
- SPRY3 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.394); catalogued as COSV57142232; called by muse, mutect2, varscan2
- SST | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs746348246, COSV55030540, COSV55031358; called by muse, mutect2, varscan2
- TBC1D32 | c.520T>A p.L174I | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV51539348; called by muse, mutect2, varscan2
- TBX22 | c.61A>C p.K21Q | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.946); catalogued as COSV64785347, COSV64785887; called by muse, mutect2, varscan2
- TDRD7 | c.3122G>A p.R1041Q | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377340161, COSV62428261, COSV62430238; called by muse, mutect2, varscan2
- TESK2 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs545470915, COSV59150417; called by muse, mutect2, varscan2
- TFPI | c.429T>G p.Y143* | Nonsense Mutation (SNP) | VAF 52/289 reads (18%) | catalogued as COSV51899635; called by muse, mutect2, varscan2
- TGM2 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63931229; called by muse, mutect2, varscan2
- TLE4 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 23/165 reads (14%) | catalogued as COSV54626871; called by muse, mutect2, varscan2
- TMEFF2 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.197); catalogued as rs376482759, COSV55829970; called by muse, mutect2, varscan2
- TRANK1 | c.5933A>G p.Q1978R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as COSV57145120; called by muse, mutect2, varscan2
- USP9X | c.4220T>G p.L1407R | Missense Mutation (SNP) | VAF 210/244 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61067316; called by muse, mutect2
- USP9X | c.4439A>C p.N1480T | Missense Mutation (SNP) | VAF 88/515 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV61067322; called by muse, mutect2, varscan2
- WDFY3 | c.7472G>T p.R2491L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV55696565; called by muse, mutect2, varscan2
- WDR19 | c.62G>A p.W21* | Nonsense Mutation (SNP) | VAF 52/136 reads (38%) | catalogued as COSV56463204; called by muse, mutect2, varscan2
- WT1 | c.1166G>A p.R389K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.535); catalogued as COSV60068261, COSV60084649; called by muse, mutect2, varscan2
- WWP1 | c.263T>A p.L88* | Nonsense Mutation (SNP) | VAF 81/549 reads (15%) | catalogued as COSV55357551; called by muse, mutect2, varscan2
- WWP1 | c.264A>T p.L88F | Missense Mutation (SNP) | VAF 82/551 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.884); catalogued as COSV55357561; called by muse, mutect2, varscan2
- XCR1 | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV58569310; called by muse, mutect2, varscan2
- ZACN | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs746472319, COSV100135303; called by muse, mutect2, varscan2
- ZBTB46 | c.944A>G p.D315G | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99829218; called by muse, mutect2, varscan2
- ZFP82 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs773772574, COSV67564937; called by muse, mutect2, varscan2
- ZNF473 | c.1591A>C p.K531Q | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV54522470; called by muse, mutect2, varscan2
- ABTB1 | c.566_573del p.E189Gfs*22 (on ENST00000232744 / NM_172027.3; = p.E47Gfs*22 on NM_032548.3) | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | called by mutect2, pindel, varscan2
- ADAMTSL4 | c.769_781del p.A257Sfs*9 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- FCGBP | c.5676C>A p.C1892* | Nonsense Mutation (SNP) | VAF 54/344 reads (16%) | called by muse, mutect2, varscan2
- PPFIA2 | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 11/277 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- RRM2 | c.535_537del p.L179del | In Frame Del (DEL) | VAF 48/144 reads (33%) | called by pindel, varscan2
- ACIN1 | c.1014G>T p.G338= | Silent (SNP) | VAF 173/776 reads (22%) | catalogued as COSV52974537; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2658C>T p.I886= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as rs1028560802; called by muse, mutect2, varscan2
- AP5S1 | c.462G>A p.A154= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as rs138405532; called by muse, mutect2, varscan2
- APIP | c.597G>T p.V199= | Silent (SNP) | VAF 110/485 reads (23%) | catalogued as COSV53506342; called by muse, mutect2, varscan2
- ARAP1 | c.1641C>T p.N547= (on ENST00000393609 / NM_001040118.2; = p.N302= on NM_015242.4) | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV61990238; called by muse, mutect2, varscan2
- BEGAIN | c.837G>A p.P279= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs761703451, COSV62068300; called by muse, mutect2
- BRAT1 | c.363C>T p.S121= | Silent (SNP) | VAF 71/137 reads (52%) | catalogued as rs1411961897, COSV100500492, COSV61396908; called by muse, mutect2, varscan2
- CALU | c.195A>C p.T65= | Silent (SNP) | VAF 31/149 reads (21%) | catalogued as COSV50821403; called by muse, mutect2, varscan2
- CDCA2 | c.2187T>C p.P729= | Silent (SNP) | VAF 83/129 reads (64%) | catalogued as COSV57945072; called by muse, mutect2, varscan2
- CELF2 | c.969C>T p.T323= (on ENST00000416382 / NM_001025077.3; = p.T330= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 28/187 reads (15%) | catalogued as COSV100257624; called by muse, mutect2, varscan2
- CFAP20DC | c.1455A>G p.R485= (on ENST00000482387 / NM_001351530.2; = p.R360= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/306 reads (7%) | catalogued as COSV99918792; called by muse, mutect2
- COQ8B | c.309G>T p.G103= | Silent (SNP) | VAF 47/90 reads (52%) | catalogued as COSV54686219; called by muse, mutect2, varscan2
- EPHA8 | c.669G>A p.S223= | Silent (SNP) | VAF 44/85 reads (52%) | catalogued as COSV51265124; called by muse, mutect2, varscan2
- EZH2 | c.1857T>G p.S619= (on ENST00000460911 / NM_001203247.2; = p.S624= on NM_004456.5) | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV100235716; called by muse, mutect2
- FGF13 | c.24G>A p.S8= | Silent (SNP) | VAF 73/82 reads (89%) | catalogued as COSV59544016; called by muse, mutect2, varscan2
- FNDC1 | c.2880G>A p.T960= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV51936392; called by muse, mutect2
- FOXD4L4 | c.111C>T p.D37= | Silent (SNP) | VAF 96/783 reads (12%) | catalogued as rs1411002544; called by muse, mutect2, varscan2
- H2AC20 | c.150C>G p.V50= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV100479953; called by muse, mutect2, varscan2
- HOXB5 | c.246G>A p.E82= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV53313333; called by muse, mutect2
- IFI27L2 | c.30G>A p.V10= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV99463095; called by muse, mutect2, varscan2
- IGKV2D-29 | c.273G>T p.G91= | Silent (SNP) | VAF 165/526 reads (31%) | catalogued as rs1300918220, COSV101534378; called by muse, mutect2, varscan2
- ITIH5 | c.2184C>T p.P728= | Silent (SNP) | VAF 57/97 reads (59%) | catalogued as rs543300408, COSV99904731, COSV99904745; called by muse, mutect2, varscan2
- KMT2D | c.15870C>T p.G5290= | Silent (SNP) | VAF 35/111 reads (32%) | catalogued as rs776989239, COSV56423202; called by muse, mutect2, varscan2
- LTBP1 | c.1575G>A p.G525= (on ENST00000404816 / NM_206943.4; = p.G199= on NM_000627.4) | Silent (SNP) | VAF 57/144 reads (40%) | catalogued as rs766063280, COSV63183185; called by muse, mutect2, varscan2
- MAGI2 | c.3195C>T p.H1065= | Silent (SNP) | VAF 116/334 reads (35%) | catalogued as rs144743202; called by muse, mutect2, varscan2
- MAP4K4 | c.3423G>A p.G1141= (on ENST00000347699 / NM_001242559.2; = p.G1067= on NM_004834.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/217 reads (36%) | catalogued as COSV56327942; called by muse, mutect2, varscan2
- MDN1 | c.8277C>T p.I2759= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV65519209; called by muse, mutect2, varscan2
- MGAT5B | c.204C>A p.R68= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as COSV56927211; called by muse, mutect2, varscan2
- MKRN3 | c.213C>A p.G71= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100091164; called by muse, mutect2, varscan2
- MMS22L | c.3432C>T p.C1144= | Silent (SNP) | VAF 47/300 reads (16%) | catalogued as COSV51518104; called by muse, mutect2, varscan2
- MRPS17 | c.33A>G p.R11= | Silent (SNP) | VAF 78/247 reads (32%) | catalogued as COSV53392233; called by muse, mutect2, varscan2
- MTA3 | c.1083T>C p.N361= | Silent (SNP) | VAF 47/162 reads (29%) | catalogued as COSV68133478; called by muse, mutect2, varscan2
- MYO5A | c.5124G>A p.K1708= | Silent (SNP) | VAF 34/110 reads (31%) | catalogued as COSV62558273; called by muse, mutect2, varscan2
- MYOM2 | c.939C>T p.R313= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as rs139950018; called by muse, mutect2, varscan2
- NELFA | c.1305G>A p.Q435= (on ENST00000542778; = p.Q424= on NM_005663.5) | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs372981689; called by muse, mutect2, varscan2
- NLGN4X | c.892C>A p.R298= | Silent (SNP) | VAF 20/327 reads (6%) | catalogued as COSV99321935; called by muse, mutect2
- NOTCH1 | c.3945C>T p.P1315= | Silent (SNP) | VAF 37/91 reads (41%) | catalogued as rs747848111, COSV53038827; called by muse, mutect2, varscan2
- OR10G3 | c.60A>C p.P20= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100336102; called by muse, mutect2
- PCDHA6 | c.2202G>A p.A734= | Silent (SNP) | VAF 59/131 reads (45%) | catalogued as rs782325255, COSV65343043; called by muse, mutect2, varscan2
- PCDHA8 | c.1296G>A p.S432= | Silent (SNP) | VAF 79/155 reads (51%) | catalogued as rs781791658, COSV65335498; called by muse, mutect2, varscan2
- PCDHB8 | c.1557G>A p.S519= | Silent (SNP) | VAF 92/453 reads (20%) | catalogued as COSV50758202; called by muse, varscan2
- PLA2G15 | c.810G>A p.L270= | Silent (SNP) | VAF 29/51 reads (57%) | catalogued as COSV54722741; called by muse, mutect2, varscan2
- PNMA8B | c.1251C>G p.T417= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100885419; called by muse, mutect2
- RASGRF1 | c.1347C>A p.I449= | Silent (SNP) | VAF 93/283 reads (33%) | catalogued as COSV101369645, COSV69183613; called by muse, mutect2, varscan2
- SALL1 | c.2157C>T p.S719= | Silent (SNP) | VAF 60/320 reads (19%) | catalogued as rs767520002, COSV51755184; called by muse, mutect2, varscan2
- SEC14L1 | c.1314C>A p.P438= | Silent (SNP) | VAF 130/201 reads (65%) | catalogued as COSV66721420; called by muse, mutect2, varscan2
- SERPINE3 | c.390C>T p.H130= | Silent (SNP) | VAF 123/213 reads (58%) | catalogued as rs767321197, COSV68545037; called by muse, mutect2, varscan2
- SOX11 | c.1179G>A p.S393= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs1384690500, COSV58984034; called by muse, mutect2, varscan2
- STXBP4 | c.885T>C p.D295= | Silent (SNP) | VAF 42/268 reads (16%) | catalogued as rs1319580481, COSV100178176; called by muse, mutect2
- TEDC1 | c.1449C>A p.A483= (on ENST00000392523 / NM_001367178.1; = p.A414= on NM_001134875.1) | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV100322226, COSV58153153; called by muse, mutect2
- TGM7 | c.1635C>A p.P545= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV71772658; called by muse, mutect2, varscan2
- TSPYL6 | c.480C>T p.A160= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as COSV57813194; called by muse, mutect2, varscan2
- UCMA | c.42C>T p.A14= | Silent (SNP) | VAF 68/104 reads (65%) | catalogued as rs748011436, COSV66321399; called by muse, mutect2, varscan2
- UGT3A2 | c.837A>C p.V279= | Silent (SNP) | VAF 73/328 reads (22%) | catalogued as COSV99236403; called by muse, mutect2, varscan2
- UNC5B | c.1734C>T p.Y578= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as rs770825448, COSV100100777; called by muse, mutect2, varscan2
- USP25 | c.312A>G p.R104= | Silent (SNP) | VAF 96/392 reads (24%) | catalogued as rs1174643795, COSV53482563; called by muse, varscan2
- WNK2 | c.3993C>G p.P1331= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs778896854, COSV52936053; called by muse, mutect2
- ZC3H12D | c.537C>T p.D179= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV66323930; called by muse, mutect2, varscan2
- DHRS4L1 | n.82C>G | RNA (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- VKORC1 | chr16:31095626 C>T | 5'Flank (SNP) | VAF 48/147 reads (33%) | catalogued as rs1567423085, COSV100161751; called by muse, mutect2, varscan2
